Somatic mutation profile of tumor specimen 0DFKH7 from CCDI case PBBRFR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.5 years (4,946 days).
Specimen 0DFKH7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 25d4098f-9a08-478e-8304-3a0ce3e63156.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFKH8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a1acd952-b2ed-447d-a94d-0dd09fb249ec

The open-access MAF lists 29 somatic variants for this specimen: 19 protein-altering or splice-affecting, 3 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Intron 5, Silent 3, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 360/378 reads (95%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- BAHCC1 | c.5446G>A p.G1816R | Missense Mutation (SNP) | VAF 200/443 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); catalogued as rs1367350215; called by muse, varscan2
- CARMIL2 | c.3259G>A p.A1087T | Missense Mutation (SNP) | VAF 288/642 reads (45%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs375479502, COSV54667427; called by muse, varscan2
- COL17A1 | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 366/827 reads (44%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.974); catalogued as rs202160225, COSV62225451; called by muse, varscan2
- GPR45 | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 248/501 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758780573, COSV99307288; called by muse, varscan2
- LARP4 | c.1378A>G p.I460V | Missense Mutation (SNP) | VAF 306/704 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs1043750286; called by muse, varscan2
- MROH7 | c.172G>A p.V58I | Missense Mutation (SNP) | VAF 164/328 reads (50%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs761828972, COSV59868198; called by muse, varscan2
- PAPPA2 | c.4006C>T p.H1336Y | Missense Mutation (SNP) | VAF 318/753 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62803742; called by muse, varscan2
- PLCH2 | c.2761G>A p.V921I | Missense Mutation (SNP) | VAF 356/728 reads (49%) | SIFT tolerated (0.83); PolyPhen benign (0.006); catalogued as rs533443137; called by muse, varscan2
- RANBP2 | c.4865G>C p.S1622T | Missense Mutation (SNP) | VAF 364/1205 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs372335602; called by muse, varscan2
- SYNE1 | c.20692G>A p.V6898I (on ENST00000367255 / NM_182961.4; = p.V6827I on NM_033071.3) | Missense Mutation (SNP) | VAF 284/640 reads (44%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.859); catalogued as rs769943110, COSV54979018; ClinVar: uncertain significance; called by muse, varscan2
- TIAM2 | c.829C>A p.L277I | Missense Mutation (SNP) | VAF 316/706 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1260742203; called by muse, varscan2
- CPNE4 | c.1259T>C p.V420A | Missense Mutation (SNP) | VAF 354/824 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); called by muse, varscan2
- EXTL3 | c.341T>C p.I114T | Missense Mutation (SNP) | VAF 262/521 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.391); called by muse, varscan2
- GPRASP1 | c.3946G>T p.A1316S | Missense Mutation (SNP) | VAF 262/608 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.55); called by muse, varscan2
- SOX30 | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 188/404 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.133); called by muse, varscan2
- SRM | c.859G>T p.A287S | Missense Mutation (SNP) | VAF 270/606 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.24); called by muse, varscan2
- TPTE | c.880C>A p.H294N (on ENST00000618007 / NM_199261.4; = p.H276N on NM_199259.4) | Missense Mutation (SNP) | VAF 150/1356 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, varscan2
- TTN | c.94208C>G p.A31403G (on ENST00000591111; = p.A23979G on NM_003319.4) | Missense Mutation (SNP) | VAF 372/734 reads (51%) | PolyPhen benign (0.443); called by muse, varscan2
- DNAH3 | c.8361G>A p.S2787= | Silent (SNP) | VAF 242/449 reads (54%) | catalogued as rs770043942, COSV54505981; called by muse, varscan2
- KIAA1210 | c.4332G>A p.G1444= | Silent (SNP) | VAF 270/659 reads (41%) | catalogued as rs781683662; called by muse, varscan2
- TRPC4 | c.1230C>G p.V410= | Silent (SNP) | VAF 245/521 reads (47%) | catalogued as COSV100157816; called by muse, varscan2
- CARD11 | c.2143-32G>A | Intron (SNP) | VAF 276/627 reads (44%) | catalogued as rs772844987; called by muse, varscan2
- DCAF8L1 | c.-64T>C | 5'UTR (SNP) | VAF 227/454 reads (50%) | called by muse, varscan2
- METTL25 | c.259+56A>G | Intron (SNP) | VAF 74/162 reads (46%) | called by muse, varscan2
- OR4C3 | c.*1G>A | 3'UTR (SNP) | VAF 162/366 reads (44%) | catalogued as rs750720644; called by muse, varscan2
- REPS1 | c.1971+32C>T | Intron (SNP) | VAF 85/205 reads (41%) | catalogued as rs1383829848; called by muse, varscan2
- STRAP | c.775+88T>A | Intron (SNP) | VAF 6/40 reads (15%) | called by muse, varscan2
- ZMYM3 | c.2148+19C>T | Intron (SNP) | VAF 294/690 reads (43%) | catalogued as rs750587261; called by muse, varscan2
